Somatic mutation profile of tumor specimen TCGA-A3-3380-01A (aliquot TCGA-A3-3380-01A-01D-0966-08) from TCGA case TCGA-A3-3380, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 54.3 years (19,828 days).
Specimen TCGA-A3-3380-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc4745f1-19de-4d1c-90f7-cc68aa65bb68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3380-11A (Solid Tissue Normal), aliquot TCGA-A3-3380-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/768808f3-252d-43f0-94f1-f760ed86fa5f

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 23, Silent 7, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.320G>C p.R107P | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs193922609, CM023996, CM982004, COSV56549138, COSV56566246; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- ACLY | c.1592A>C p.Y531S | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV61251323; called by muse, mutect2, varscan2
- C2CD3 | c.707+1G>A p.X236_splice | Splice Site (SNP) | VAF 241/800 reads (30%) | catalogued as rs778349032, COSV58094748; called by muse, mutect2, varscan2
- CLSTN3 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 87/273 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56937682; called by muse, mutect2, varscan2
- CLSTN3 | c.538A>G p.I180V | Missense Mutation (SNP) | VAF 88/275 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as COSV56937699; called by muse, mutect2, varscan2
- CTSB | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1342365560, COSV61540386, COSV61540872; called by muse, mutect2, varscan2
- DQX1 | c.2085G>A p.M695I | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs554672292, COSV52046389, COSV99283569; called by muse, mutect2, varscan2
- GRIN2B | c.1293G>T p.R431S | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV74205754, COSV74206520; called by muse, mutect2, varscan2
- ICE1 | c.3482T>G p.I1161R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV56827836; called by muse, mutect2, varscan2
- IDH1 | c.855T>G p.Y285* | Nonsense Mutation (SNP) | VAF 36/121 reads (30%) | catalogued as COSV61628724; called by muse, mutect2, varscan2
- KANSL1L | c.499C>A p.Q167K | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV55993693; called by muse, mutect2, varscan2
- KCNK18 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs139101102; called by muse, mutect2, varscan2
- KCNRG | c.779A>G p.E260G | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV57249125; called by muse, mutect2, varscan2
- LPCAT3 | c.962T>C p.V321A | Missense Mutation (SNP) | VAF 94/345 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as COSV54642512; called by muse, mutect2, varscan2
- OR10G2 | c.704C>G p.T235S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.275); catalogued as rs1413798759, COSV73390407; called by muse, mutect2
- OR4C13 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 117/489 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs781818106, COSV73648808; called by muse, mutect2, varscan2
- PCLO | c.6981G>T p.E2327D | Missense Mutation (SNP) | VAF 143/470 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV61644662; called by muse, mutect2, varscan2
- PRCC | c.1366C>A p.Q456K | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54857004; called by muse, mutect2, varscan2
- PROKR1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs780773340, COSV58136990; called by muse, mutect2, varscan2
- SBF1 | c.4712G>A p.R1571K | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1371487529, COSV62368469; called by muse, mutect2, varscan2
- SLX4 | c.2460G>T p.R820S | Missense Mutation (SNP) | VAF 92/385 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV53565433; called by muse, mutect2, varscan2
- TOB2 | c.968T>C p.L323P | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59501265; called by muse, mutect2, varscan2
- WIZ | c.4200G>T p.K1400N (on ENST00000673675 / NM_001371589.1; = p.K305N on NM_021241.3) | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54609077; called by muse, mutect2, varscan2
- ZBTB49 | c.1786C>A p.L596M | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.336); catalogued as COSV61925362; called by muse, mutect2, varscan2
- ZNF836 | c.2146C>G p.P716A | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs760797888, COSV59081273, COSV59083990; called by muse, mutect2, varscan2
- PTPN12 | c.1350del p.F450Lfs*7 | Frame Shift Del (DEL) | VAF 47/199 reads (24%) | called by mutect2, pindel, varscan2
- ABCD1 | c.2031C>T p.G677= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs782468372, COSV54385890; called by muse, mutect2
- B3GAT2 | c.501G>A p.L167= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV57772051; called by muse, mutect2, varscan2
- LFNG | c.87G>A p.R29= | Silent (SNP) | VAF 65/274 reads (24%) | catalogued as rs1239480077, COSV101273404; called by muse, mutect2, varscan2
- PCDHGA3 | c.2028C>G p.G676= | Silent (SNP) | VAF 35/270 reads (13%) | catalogued as COSV53974424, COSV99533414; called by muse, mutect2, varscan2
- PLAG1 | c.273C>A p.T91= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV57612700; called by muse, mutect2, varscan2
- RNF151 | c.435C>A p.G145= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV58400245; called by muse, mutect2
- SPAG9 | c.861A>G p.T287= (on ENST00000262013 / NM_001130528.3; = p.T273= on NM_003971.6) | Silent (SNP) | VAF 154/457 reads (34%) | catalogued as rs373565315; called by muse, mutect2, varscan2
